Somatic mutation profile of tumor specimen MMRF_1128_1_BM_CD138pos (aliquot MMRF_1128_1_BM_CD138pos_T2_TSE61_K03604) from MMRF case MMRF_1128, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.6 years (17,765 days).
Specimen MMRF_1128_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b787659-f4ad-4220-8c03-0618f3372dd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1128_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1128_1_PB_Whole_C1_TSE61_K03603; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c269c67a-a3b3-4945-97b9-c6294d0518c7

The open-access MAF lists 60 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 14, Silent 8, 5'UTR 3, Intron 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.3087C>G p.S1029R | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs926516356; called by muse, mutect2, varscan2
- CARD11 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV62756393, COSV62756695; called by muse, mutect2, varscan2
- CCDC80 | c.2582C>A p.P861Q | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99244135; called by muse, mutect2, varscan2
- CDK12 | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1308424951; called by muse, mutect2, varscan2
- CRISPLD2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1203623828; called by muse, mutect2, varscan2
- DNAH2 | c.5749G>A p.E1917K | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs771959734, COSV101209101; called by muse, mutect2, varscan2
- IL18R1 | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1437318298; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.677); catalogued as COSV100148886; called by muse, mutect2, varscan2
- LIG1 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771000990, COSV54396504; called by muse, mutect2, varscan2
- NRP2 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55924275; called by muse, mutect2, varscan2
- NRP2 | c.2402T>C p.M801T | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs1238554121; called by muse, mutect2, varscan2
- SEZ6L2 | c.929G>A p.G310D (on ENST00000308713 / NM_001114099.3; = p.G240D on NM_012410.4) | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752413264, COSV58104348; called by muse, mutect2, varscan2
- TMEM177 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs550216529; called by muse, mutect2, varscan2
- VSTM1 | c.682T>A p.S228T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV58074233; called by muse, mutect2, varscan2
- ZC3H4 | c.399C>G p.S133R | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99453007; called by muse, mutect2, varscan2
- ALG9 | c.960G>T p.L320F | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ATP13A3 | c.2439G>T p.L813F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2
- CARD14 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CXCR4 | c.1056C>A p.S352R | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DNAH8 | c.8789C>T p.T2930I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HNRNPH1 | c.1297T>C p.Y433H | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- INSM2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNK2 | c.937G>T p.V313L (on ENST00000444842 / NM_001017425.3; = p.V298L on NM_014217.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- KMT2C | c.3128C>T p.T1043I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NDUFB10 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2
- PHTF1 | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- PLG | c.2096G>A p.C699Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPL3L | c.633C>A p.F211L | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- SLIT3 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TAF3 | c.2154G>T p.K718N | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAF3 | c.226T>A p.C76S | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR86 | c.181A>T p.T61S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- DNAH10 | c.11481C>T p.C3827= (on ENST00000409039; = p.C3766= on NM_207437.3) | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs747963405; called by muse, mutect2, varscan2
- DOLK | c.789C>T p.T263= | Silent (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- DSG3 | c.528G>A p.V176= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV57126455; called by muse, varscan2
- MYPN | c.3084C>T p.I1028= | Silent (SNP) | VAF 32/33 reads (97%) | called by muse, mutect2, varscan2
- ORC4 | c.1310G>A p.*437= | Silent (SNP) | VAF 63/92 reads (68%) | catalogued as rs1273001070, COSV99605215; called by muse, mutect2, varscan2
- PNPO | c.321C>T p.F107= | Silent (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- SMO | c.1590C>T p.I530= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs184087073; called by muse, mutect2, varscan2
- VIM | c.651T>A p.R217= | Silent (SNP) | VAF 46/46 reads (100%) | called by muse, mutect2, varscan2
- A1BG | c.*134G>T | 3'UTR (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- ARAP1 | c.509+4543A>G | Intron (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2
- CACNA2D4 | c.-35C>T | 5'UTR (SNP) | VAF 14/32 reads (44%) | catalogued as rs370004639; called by muse, mutect2, varscan2
- HAPLN1 | c.*1081A>G | 3'UTR (SNP) | VAF 22/59 reads (37%) | catalogued as rs1042371007; called by muse, mutect2, varscan2
- HMGB4 | c.-1238T>G | 5'UTR (SNP) | VAF 31/34 reads (91%) | called by muse, mutect2, varscan2
- IRF8 | c.*968T>G | 3'UTR (SNP) | VAF 25/26 reads (96%) | called by muse, mutect2, varscan2
- KIAA1217 | chr10:24209063 G>T | 5'Flank (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- LHX9 | c.-341A>T | 5'UTR (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- MCC | c.*1432G>A | 3'UTR (SNP) | VAF 46/95 reads (48%) | catalogued as rs892609707; called by muse, mutect2, varscan2
- PLA2G2D | c.*1495G>C | 3'UTR (SNP) | VAF 26/28 reads (93%) | called by muse, mutect2, varscan2
- PUM2 | c.*618A>G | 3'UTR (SNP) | VAF 12/30 reads (40%) | catalogued as rs886569805; called by muse, mutect2, varscan2
- RFX3 | c.1968+702G>A | Intron (SNP) | VAF 24/35 reads (69%) | called by muse, mutect2, varscan2
- SEMA3E | c.*1296T>G | 3'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs1042873393; called by muse, mutect2, varscan2
- SLC38A3 | c.*245T>G | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- SLC7A11 | c.*4397C>T | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- SPNS2 | c.*260G>A | 3'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- TMEM63C | c.*202G>T | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TRIM5 | c.*527C>A | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- USP44 | c.*479G>T | 3'UTR (SNP) | VAF 57/110 reads (52%) | called by muse, mutect2, varscan2
- ZNF654 | c.*1062C>G | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
